Gene-level copy-number profile of tumor specimen MP2PRT-PARYIZ-TMP1-A from MP2PRT case MP2PRT-PARYIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (731 days).
Specimen MP2PRT-PARYIZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fca1fcaf-9ff8-4a68-90ab-6099fe7899a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARYIZ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/5623bced-dfb5-4046-9b33-63f2ccfbc7af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 217; copy number 1: 2,845; copy number 2: 55,745; copy number 3: 91.

Homozygous deletions (total copy number 0; autosomes only): 212 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,234,912, 36 genes (within-gene range 0–2): IGKC, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:89,947,512–90,022,185, 9 genes: IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:90,179,889–90,221,384, 4 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr6:26,156,329–26,273,412, 26 genes: H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–1): TRGV5P, TRGV5.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 120. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
